Somatic mutation profile of tumor specimen TCGA-EI-6885-01A (aliquot TCGA-EI-6885-01A-11D-1924-10) from TCGA case TCGA-EI-6885, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.9 years (21,140 days).
Specimen TCGA-EI-6885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2f6d55b-efb8-4a56-b84e-1d50ccedf5eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6885-10A (Blood Derived Normal), aliquot TCGA-EI-6885-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c00222bb-9de0-4429-b129-426feecb52e4

The open-access MAF lists 109 somatic variants for this specimen: 79 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 29, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 163/223 reads (73%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.156dup p.W53Mfs*4 | Frame Shift Ins (INS) | VAF 24/46 reads (52%) | catalogued as rs1555526748; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC2 | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV64970968; called by muse, mutect2, varscan2
- AFAP1 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.542); catalogued as rs1288459363, COSV61796257; called by muse, mutect2, varscan2
- ANAPC1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV61976833; called by muse, mutect2, varscan2
- ARFGEF1 | c.4781C>A p.A1594D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV51610473; called by muse, mutect2, varscan2
- ATP7A | c.4246G>A p.E1416K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs781970260, COSV58446610; called by muse, mutect2, varscan2
- ATP8A2 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs964854316, COSV99682406, COSV99683173; called by muse, varscan2
- AUTS2 | c.2320A>G p.M774V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1158235085, COSV61409402; called by muse, mutect2, varscan2
- BDKRB2 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV100021249; called by muse, mutect2, varscan2
- C6 | c.1742A>G p.Y581C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1314588998, COSV54711862; called by muse, mutect2, varscan2
- C8B | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs548519847, COSV64778097; called by muse, mutect2, varscan2
- CACNA1E | c.5729A>G p.E1910G | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV62400976; called by muse, mutect2, varscan2
- CARD14 | c.3005G>A p.S1002N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58339486; called by muse, mutect2, varscan2
- CBLN1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV54654232; called by muse, mutect2, varscan2
- CDH23 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs373422805; called by mutect2, varscan2
- CHST3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100910468; called by muse, mutect2, varscan2
- CLDN8 | c.156G>C p.M52I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54526209; called by muse, mutect2, varscan2
- DAGLA | c.830A>T p.Y277F | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.956); catalogued as COSV99944465; called by muse, varscan2
- DENND4B | c.2312G>A p.C771Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63409347; called by muse, mutect2, varscan2
- DMXL1 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 139/191 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60713988; called by muse, mutect2, varscan2
- DNM2 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58963411; called by muse, varscan2
- FUT8 | c.1675C>T p.R559* (on ENST00000360689 / NM_001371534.1; = p.R396* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as rs769250336, COSV61280757; called by muse, mutect2, varscan2
- GLI3 | c.3312C>A p.N1104K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV67889772; called by muse, mutect2, varscan2
- GPATCH2 | c.927T>A p.D309E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV65127945; called by muse, mutect2, varscan2
- GUCY1A2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as rs767475685, COSV56493619, COSV99975077; called by muse, mutect2
- HECTD4 | c.4649G>A p.R1550H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.427); catalogued as rs779647953, COSV66393689; called by muse, mutect2, varscan2
- HK2 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769519345, COSV51876176, COSV51880154; called by muse, mutect2, varscan2
- HNRNPH2 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV54509580; called by muse, mutect2, varscan2
- ITIH1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.051); catalogued as rs144224070, COSV56255906, COSV56257471; called by muse, mutect2, varscan2
- KCNV1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1458883589, COSV52084840; called by muse, mutect2
- KIR2DL1 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs749328195; called by muse, mutect2, varscan2
- MAGEA11 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100290551; called by muse, mutect2
- MBNL2 | c.1021G>A p.G341R (on ENST00000376673 / NM_001382666.1; = p.G329R on NM_207304.3 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs369342078; called by muse, mutect2, varscan2
- MCMDC2 | c.1761A>T p.L587F | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58036861; called by muse, mutect2
- MYO7A | c.3784G>A p.V1262M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370036829; called by muse, mutect2, varscan2
- NTSR1 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65138503; called by muse, mutect2, varscan2
- OR2T27 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs145097433, COSV100788284; called by mutect2, varscan2
- PCDHGB2 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs573308473, COSV53966534; called by muse, mutect2, varscan2
- PCSK7 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309401; called by muse, varscan2
- PKD1L1 | c.2724G>C p.W908C | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548542107, COSV56967994; called by muse, mutect2, varscan2
- PLA2G5 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV64283094; called by muse, mutect2, varscan2
- PNLIPRP3 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV65048550; called by muse, mutect2, varscan2
- PRDM2 | c.5059C>T p.R1687* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs868853426, COSV52448614, COSV52448880; called by muse, mutect2, varscan2
- PRRC2B | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622081, COSV61938338; called by muse, mutect2, varscan2
- PTPN3 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52706977; called by muse, mutect2, varscan2
- PUS10 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs573372866, COSV100369580; called by muse, mutect2, varscan2
- RB1CC1 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 27/383 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV99212343; called by muse, mutect2
- SGCG | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV54562131; called by muse, mutect2, varscan2
- SHROOM2 | c.1393A>C p.S465R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66607556; called by muse, mutect2
- SLC25A30 | c.617C>G p.S206* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs1336412433, COSV60433950; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- SLCO1B1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV57012370, COSV57016415; called by muse, mutect2, varscan2
- SLITRK5 | c.2368C>T p.H790Y | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs766013136, COSV61523507; called by muse, mutect2, varscan2
- SPAG16 | c.627A>C p.L209F | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55986623, COSV99793773; called by muse, mutect2, varscan2
- SPATC1L | c.538C>G p.L180V (on ENST00000291672 / NM_001142854.2; = p.L26V on NM_032261.5) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV99386042; called by muse, mutect2, varscan2
- TANGO6 | c.3070G>C p.V1024L | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55766929; called by muse, mutect2, varscan2
- TATDN2 | c.1577T>C p.F526S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99813575; called by muse, mutect2, varscan2
- TENM3 | c.5644G>A p.E1882K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs775010852, COSV69306263; called by muse, varscan2
- TRAPPC8 | c.2183C>G p.S728C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.428); catalogued as COSV51972550; called by muse, mutect2, varscan2
- TRIML2 | c.1253G>T p.S418I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV58717136; called by muse, mutect2, varscan2
- TSHZ3 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs747619045, COSV53674233; called by muse, mutect2, varscan2
- VPS13B | c.3415T>G p.F1139V | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62145623; called by muse, mutect2, varscan2
- VPS9D1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66994575; called by muse, mutect2, varscan2
- WIZ | c.4423G>A p.E1475K (on ENST00000673675 / NM_001371589.1; = p.E380K on NM_021241.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV54608546; called by muse, mutect2, varscan2
- YLPM1 | c.4254A>C p.E1418D | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV53114066; called by muse, mutect2, varscan2
- ZNF169 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762656741, COSV61764168; called by muse, mutect2, varscan2
- ZNF324 | c.1195T>C p.C399R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52181100; called by muse, mutect2, varscan2
- ZNF462 | c.3532C>T p.R1178* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52949534; called by mutect2, varscan2
- ZNF517 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as rs906386686, COSV100743679; called by muse, mutect2, varscan2
- ZNF680 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV59016257; called by muse, mutect2, varscan2
- ZNF862 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56224420; called by muse, mutect2, varscan2
- EMG1 | c.596_597dup p.V200Wfs*2 | Frame Shift Ins (INS) | VAF 28/90 reads (31%) | called by pindel, varscan2
- EMG1 | c.599dup p.G201Rfs*21 | Frame Shift Ins (INS) | VAF 40/101 reads (40%) | called by mutect2, varscan2*
- GAK | c.2470_2471del p.D824Rfs*3 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by pindel, varscan2
- HS3ST3B1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- IGHV4-31 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- PTPN20 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- TDGF1 | c.223+2dup p.X75_splice | Splice Site (INS) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.2373C>T p.D791= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs769078401, COSV55782484; called by muse, mutect2, varscan2
- BCR | c.723C>T p.G241= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs147209807; called by muse, mutect2
- CALCA | c.126C>T p.L42= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV59027996; called by muse, mutect2, varscan2
- CD22 | c.960G>A p.S320= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs550216523, COSV50050163; called by muse, mutect2, varscan2
- CFHR4 | c.1269C>T p.Y423= (on ENST00000367416 / NM_001201551.2; = p.Y177= on NM_006684.5) | Silent (SNP) | VAF 84/414 reads (20%) | catalogued as rs542124899, COSV52231421; called by muse, varscan2
- COL11A1 | c.1635G>T p.G545= | Silent (SNP) | VAF 135/207 reads (65%) | catalogued as COSV100615079, COSV62186140; called by muse, mutect2, varscan2
- CSF2 | c.99G>C p.V33= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV51522557; called by muse, mutect2, varscan2
- DDX60 | c.3972C>T p.G1324= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV67097244; called by muse, mutect2, varscan2
- DNAH1 | c.3870G>A p.V1290= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1420182096, COSV70230230; called by muse, mutect2, varscan2
- GALNTL6 | c.1164A>G p.V388= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV72490920; called by muse, mutect2, varscan2
- KIF21B | c.4011G>A p.T1337= (on ENST00000422435 / NM_001252100.2; = p.T1324= on NM_017596.4) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs755689975, COSV100144650; called by mutect2, varscan2
- LANCL2 | c.1053C>T p.S351= | Silent (SNP) | VAF 62/203 reads (31%) | catalogued as rs143590728; called by muse, mutect2, varscan2
- N4BP1 | c.492T>A p.V164= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as COSV52211307; called by muse, mutect2, varscan2
- OR13C4 | c.279C>A p.S93= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV52927014; called by muse, mutect2, varscan2
- PCDH17 | c.1845C>T p.S615= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV64971534; called by muse, mutect2, varscan2
- PCDHA3 | c.1461C>T p.N487= | Silent (SNP) | VAF 59/97 reads (61%) | catalogued as COSV63539232; called by muse, mutect2, varscan2
- PCNT | c.4683A>G p.E1561= | Silent (SNP) | VAF 108/178 reads (61%) | catalogued as COSV64029432; called by muse, mutect2, varscan2
- PCSK7 | c.933G>A p.G311= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100309397; called by muse, varscan2
- PRRT1 | c.798C>T p.R266= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV52998629; called by muse, mutect2, varscan2
- RPUSD2 | c.1530G>A p.L510= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV59765759; called by muse, mutect2, varscan2
- SH3BP4 | c.1434C>G p.L478= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1375667650, COSV60644347; called by muse, mutect2, varscan2
- SLCO1C1 | c.459G>A p.P153= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs146526055, COSV99859470; called by muse, mutect2, varscan2
- SPANXB1 | c.231C>T p.H77= | Silent (SNP) | VAF 100/944 reads (11%) | called by muse, varscan2
- SPANXC | c.213C>T p.H71= | Silent (SNP) | VAF 69/438 reads (16%) | catalogued as rs781789990, COSV62842040; called by muse, mutect2, varscan2
- TTC21A | c.210C>T p.D70= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs200112068, COSV57186019; called by muse, mutect2, varscan2
- TTN | c.38478G>A p.K12826= (on ENST00000591111; = p.K5402= on NM_003319.4) | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as rs751420847, COSV60127693; called by muse, mutect2, varscan2
- VSIG1 | c.666C>T p.C222= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs764140353, COSV54259760; called by muse, mutect2, varscan2
- WNT7A | c.822G>A p.S274= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53199674; called by muse, mutect2, varscan2
- ZFHX4 | c.789C>A p.S263= | Silent (SNP) | VAF 81/1458 reads (6%) | catalogued as COSV99263769; called by muse, mutect2
- ZNF99 | c.*169T>C | 3'UTR (SNP) | VAF 13/70 reads (19%) | catalogued as rs552617618, COSV101233851; called by muse, mutect2, varscan2
